Somatic mutation profile of tumor specimen 8e17b45e-6a06-4e4e-913d-7b1edb (aliquot 8e17b45e-6a06-4e4e-913d-7b1edb_D6_1) from CPTAC case 01OV039, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 8e17b45e-6a06-4e4e-913d-7b1edb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb541bd7-79e0-45fe-9bf2-95480946f7e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 360dd010-08a6-40ba-adca-6b53e5 (Blood Derived Normal), aliquot 360dd010-08a6-40ba-adca-6b53e5_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7479912-5369-4201-9a13-25cade1da8f9

The open-access MAF lists 150 somatic variants for this specimen: 99 protein-altering or splice-affecting, 24 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 24, Intron 16, Frame Shift Del 5, RNA 4, Splice Site 3, Nonsense Mutation 3, 5'Flank 3, In Frame Del 2, 5'UTR 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD16B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs1199192240; called by muse, mutect2, varscan2
- ACTL7B | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 59/428 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753133582, COSV101012598; called by muse, mutect2, varscan2
- C2orf78 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 211/355 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV68518137; called by muse, mutect2, varscan2
- CDH10 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs754465931, COSV52569054, COSV52590251; called by muse, mutect2, varscan2
- CENPE | c.6223G>C p.V2075L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV54383508; called by muse, mutect2, varscan2
- CHMP3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as rs760450254; called by mutect2, varscan2
- COL19A1 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs756958438; called by muse, mutect2, varscan2
- COL22A1 | c.4486C>T p.Q1496* | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | catalogued as COSV57348141, COSV57361247; called by muse, mutect2, varscan2
- CSPG5 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.442); catalogued as rs778383749, COSV99273917; called by muse, varscan2
- DTNA | c.1757C>G p.P586R | Missense Mutation (SNP) | VAF 104/486 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145425478; called by muse, mutect2, varscan2
- ETV1 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV54139936; called by muse, mutect2, varscan2
- FMN2 | c.4927G>A p.A1643T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as rs867574159; called by muse, mutect2, varscan2
- GAS2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as rs762930951, COSV53404462; called by muse, mutect2, varscan2
- GON4L | c.3757G>A p.E1253K | Missense Mutation (SNP) | VAF 272/651 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs779242461; called by muse, mutect2, varscan2
- IBA57 | c.757G>C p.V253L | Missense Mutation (SNP) | VAF 225/378 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100812808; called by muse, mutect2, varscan2
- LRRIQ4 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV61620395; called by muse, mutect2, varscan2
- LYST | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101090559; called by muse, mutect2, varscan2
- NFATC2 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65355553; called by muse, mutect2, varscan2
- NLGN3 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 137/168 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704549, COSV62445063; called by muse, mutect2, varscan2
- NLRP13 | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs542646998; called by muse, mutect2, varscan2
- NTRK1 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 136/342 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1392681907, COSV62329426; called by muse, mutect2, varscan2
- PANK2 | c.1354G>C p.D452H (on ENST00000316562 / NM_153638.3; = p.D161H on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57254097; called by muse, mutect2, varscan2
- PLXNA2 | c.5503G>A p.E1835K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1266409460; called by muse, mutect2, varscan2
- PPP1R37 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as rs1272214616; called by muse, mutect2, varscan2
- PRCP | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as rs947016241; called by muse, mutect2, varscan2
- RASAL2 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1251999782; called by mutect2, varscan2
- RP1L1 | c.5494G>T p.A1832S | Missense Mutation (SNP) | VAF 85/112 reads (76%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.527); catalogued as rs966642196; called by muse, mutect2, varscan2
- SPPL2C | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776072847, COSV61292262; called by muse, mutect2, varscan2
- TSC22D2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1273973807; called by muse, mutect2, varscan2
- TTC13 | c.1659G>C p.M553I | Missense Mutation (SNP) | VAF 92/160 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100792970; called by muse, mutect2, varscan2
- TTN | c.77494C>T p.P25832S (on ENST00000591111; = p.P18408S on NM_003319.4) | Missense Mutation (SNP) | VAF 117/422 reads (28%) | PolyPhen probably damaging (0.998); catalogued as COSV60225177; called by muse, mutect2, varscan2
- VWA3A | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV67013419; called by muse, mutect2, varscan2
- ABCC11 | c.2737A>G p.T913A | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, varscan2
- ACKR4 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ADCY1 | c.2567A>T p.N856I | Missense Mutation (SNP) | VAF 101/394 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ADGRF5 | c.3510G>C p.K1170N | Missense Mutation (SNP) | VAF 117/259 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AKR1D1 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALOXE3 | c.957+1G>T p.X319_splice | Splice Site (SNP) | VAF 135/530 reads (25%) | called by muse, mutect2, varscan2
- ARMCX6 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 158/207 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ARNTL2 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BHLHE23 | c.470C>A p.A157D (on ENST00000370346; = p.A173D on NM_080606.4) | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CAMKV | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 152/348 reads (44%) | called by muse, mutect2, varscan2
- CAND2 | c.3592C>A p.P1198T (on ENST00000456430 / NM_001162499.2; = p.P1081T on NM_012298.3) | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CFAP54 | c.595T>G p.C199G | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CHCHD1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CLVS1 | c.788A>T p.H263L | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CNDP1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CST3 | c.414G>C p.L138F | Missense Mutation (SNP) | VAF 207/723 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CTC1 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- CUBN | c.2069T>C p.I690T | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAAH2 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM114A1 | c.978_979del p.K327Afs*7 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by pindel, varscan2
- FHOD3 | c.2866del p.Q956Kfs*18 (on ENST00000359247 / NM_001281739.3; = p.Q973Kfs*18 on NM_025135.5) | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by mutect2, pindel, varscan2
- GIGYF2 | c.3426G>C p.M1142I | Missense Mutation (SNP) | VAF 112/237 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- GIT1 | c.1608C>G p.S536R | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.14); called by muse, mutect2
- GNPAT | c.1280-1G>T p.X427_splice | Splice Site (SNP) | VAF 96/372 reads (26%) | called by mutect2, varscan2
- GPN3 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 112/205 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- HSD17B6 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ID2 | c.298_342del p.R100_S114del | In Frame Del (DEL) | VAF 44/200 reads (22%) | called by mutect2, pindel, varscan2
- IL27RA | c.1784C>G p.P595R | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- KCNH5 | c.140T>C p.F47S | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIZ | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- KLK8 | c.552T>G p.C184W | Missense Mutation (SNP) | VAF 80/105 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC55 | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 141/526 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MED12 | c.4820A>T p.E1607V | Missense Mutation (SNP) | VAF 190/259 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MMP9 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MYBL2 | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- MYBPC1 | c.2585C>G p.P862R (on ENST00000550270 / NM_206820.2; = p.P869R on NM_002465.4) | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKAPD1 | c.753_787del p.R251Sfs*4 (on ENST00000280352 / NM_001082970.2; = p.R252Sfs*4 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel
- NOL6 | c.2677C>G p.P893A | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR1D2 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 66/512 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NTRK1 | c.554A>T p.H185L | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBI1 | c.1221G>C p.E407D | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- P2RY8 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 174/376 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PCDH18 | c.928A>C p.K310Q | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- PDZRN3 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 189/437 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.3578G>A p.C1193Y | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPN7 | c.749T>G p.I250S (on ENST00000495688; = p.I289S on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2
- RASGEF1A | c.100_120del p.G34_F40del | In Frame Del (DEL) | VAF 67/653 reads (10%) | called by mutect2, pindel
- RBM48 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS1 | c.3838A>G p.S1280G | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RSRP1 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCGN | c.49_55del p.F17Rfs*14 | Frame Shift Del (DEL) | VAF 30/153 reads (20%) | called by mutect2, pindel, varscan2
- SCN5A | c.1057A>C p.T353P | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- SLC47A1 | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- SPATA48 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPDL1 | c.270C>G p.H90Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK4 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TFRC | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRIM10 | c.1130del p.G377Afs*8 | Frame Shift Del (DEL) | VAF 235/340 reads (69%) | called by mutect2, pindel, varscan2
- UNC80 | c.2704A>C p.S902R | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- VSIR | c.676+2T>G p.X226_splice | Splice Site (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- VWA7 | c.2164G>C p.V722L | Missense Mutation (SNP) | VAF 150/163 reads (92%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- WIPF2 | c.980C>G p.P327R | Missense Mutation (SNP) | VAF 147/167 reads (88%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ZNF277 | c.801+5G>T | Splice Region (SNP) | VAF 55/173 reads (32%) | called by muse, mutect2, varscan2
- ZNF550 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 182/235 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF676 | c.185C>G p.P62R (on ENST00000650058; = p.P30R on NM_001001411.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF7 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF700 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AC099489.1 | c.4575C>G p.A1525= | Silent (SNP) | VAF 87/200 reads (44%) | catalogued as rs1262248339; called by muse, mutect2, varscan2
- ADGRB1 | c.2043G>C p.G681= | Silent (SNP) | VAF 59/262 reads (23%) | called by muse, mutect2, varscan2
- ALDH1A1 | c.303G>T p.L101= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV52789236; called by muse, mutect2, varscan2
- BLK | c.939G>A p.E313= | Silent (SNP) | VAF 88/104 reads (85%) | catalogued as COSV99377334; called by muse, mutect2, varscan2
- C7orf57 | c.249G>A p.L83= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs1005719393; called by muse, mutect2, varscan2
- CD1B | c.537C>T p.L179= | Silent (SNP) | VAF 83/196 reads (42%) | catalogued as rs1436035397, COSV63805230; called by muse, mutect2, varscan2
- CTNNAL1 | c.1167T>C p.S389= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- DMRTA2 | c.843T>G p.A281= | Silent (SNP) | VAF 101/289 reads (35%) | called by muse, mutect2, varscan2
- ENG | c.1056G>A p.P352= | Silent (SNP) | VAF 98/541 reads (18%) | catalogued as rs769530262, COSV100785187, COSV61228579; ClinVar: likely benign; called by muse, mutect2, varscan2
- ETFA | c.798G>A p.T266= | Silent (SNP) | VAF 80/205 reads (39%) | catalogued as rs764478797; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM114A1 | c.981G>A p.K327= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, varscan2
- HERC1 | c.5838T>C p.P1946= | Silent (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- KIT | c.483G>A p.R161= | Silent (SNP) | VAF 133/575 reads (23%) | called by muse, mutect2, varscan2
- MC3R | c.360C>T p.F120= | Silent (SNP) | VAF 230/395 reads (58%) | catalogued as rs756752693, COSV54764204, COSV54764693; called by muse, mutect2, varscan2
- MKS1 | c.63G>C p.V21= | Silent (SNP) | VAF 179/191 reads (94%) | called by muse, mutect2, varscan2
- MYO9B | c.1167G>A p.E389= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- NYX | c.849C>G p.L283= | Silent (SNP) | VAF 191/451 reads (42%) | catalogued as rs1431317390; called by muse, mutect2, varscan2
- RP1L1 | c.3477A>T p.P1159= | Silent (SNP) | VAF 180/244 reads (74%) | catalogued as COSV66751735; called by muse, mutect2, varscan2
- SLC39A14 | c.291C>A p.L97= | Silent (SNP) | VAF 36/50 reads (72%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.1809T>C p.D603= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- SVIL | c.3759C>T p.I1253= (on ENST00000355867 / NM_021738.3; = p.I827= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/200 reads (26%) | catalogued as rs1245480813, COSV100881485; called by muse, mutect2, varscan2
- TAF3 | c.580C>A p.R194= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV60211100; called by muse, mutect2
- TNR | c.1458T>C p.A486= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2, varscan2
- WDFY4 | c.5814G>C p.A1938= | Silent (SNP) | VAF 75/217 reads (35%) | called by muse, mutect2, varscan2
- AC073343.1 | n.516C>A | RNA (SNP) | VAF 54/190 reads (28%) | called by mutect2, varscan2
- AP000769.5 | chr11:65500926 G>T | 5'Flank (SNP) | VAF 54/99 reads (55%) | called by muse, mutect2, varscan2
- C2CD6 | c.1582-3564T>C | Intron (SNP) | VAF 14/239 reads (6%) | catalogued as COSV53800854; called by muse, mutect2
- CCM2 | chr7:44999701 G>A | 5'Flank (SNP) | VAF 16/85 reads (19%) | catalogued as rs1322884207; called by muse, mutect2, varscan2
- EMC4 | c.201+188G>T | Intron (SNP) | VAF 56/164 reads (34%) | called by muse, mutect2, varscan2
- F7 | c.317-32T>C | Intron (SNP) | VAF 221/1118 reads (20%) | called by muse, varscan2
- GCNT2P1 | n.741A>C | RNA (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- GSTZ1 | c.15+282C>A | Intron (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- HDC | c.788-20G>C | Intron (SNP) | VAF 95/229 reads (41%) | catalogued as rs747824449; called by muse, mutect2, varscan2
- IGHMBP2 | c.1235+1003C>A | Intron (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- ITPRID1 | c.-20+11468C>A | Intron (SNP) | VAF 21/117 reads (18%) | catalogued as COSV60076253; called by muse, mutect2, varscan2
- MUC7 | c.-1A>G | 5'UTR (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- MYBPC1 | chr12:101685665 A>C | 3'Flank (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- NACA4P | n.698T>A | RNA (SNP) | VAF 22/506 reads (4%) | called by muse, mutect2
- PCDHGA4 | c.2514+17A>G | Intron (SNP) | VAF 62/125 reads (50%) | catalogued as rs765041890, COSV53932944; called by muse, mutect2, varscan2
- PLEKHF1 | c.-17+279A>C | Intron (SNP) | VAF 21/270 reads (8%) | called by muse, mutect2
- RBM43 | c.3+351_3+376del | Intron (DEL) | VAF 68/364 reads (19%) | called by mutect2, pindel, varscan2
- RPGR | c.2520+1169T>A | Intron (SNP) | VAF 30/84 reads (36%) | catalogued as rs773842474, COSV58840003; called by mutect2, varscan2
- RUFY1 | c.1026+546G>A | Intron (SNP) | VAF 70/169 reads (41%) | called by muse, mutect2, varscan2
- SSBP4 | c.992-32G>C | Intron (SNP) | VAF 31/93 reads (33%) | catalogued as rs899457471; called by muse, mutect2, varscan2
- SYT14 | c.61+318T>G | Intron (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+3138G>C | Intron (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- TLR4 | c.*41C>A | 3'UTR (SNP) | VAF 81/374 reads (22%) | called by mutect2, varscan2
- TMEM235 | c.-445G>T | 5'UTR (SNP) | VAF 29/298 reads (10%) | called by muse, mutect2, varscan2
- TRIM41 | c.1140+79C>G | Intron (SNP) | VAF 55/120 reads (46%) | called by muse, mutect2, varscan2
- TTC41P | n.3035G>T | RNA (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776347 C>T | 5'Flank (SNP) | VAF 62/197 reads (31%) | catalogued as rs535231593; called by muse, mutect2, varscan2
